MMRF case MMRF_2601 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b9eebd22-b66c-45dd-bc5d-4bc46423bb52

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.8 years (25,861 days); ISS stage: II; Days to last known disease status: 638 days (1.7 years); Days to last follow up: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 575 days (1.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 4.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 67.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 51.3 g/L; Immunoglobulin A 0.068 g/L; Immunoglobulin M 0.095 g/L; Beta 2 Microglobulin 4.86 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.13 ×10⁹/L; Absolute Neutrophil 2.39 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 70.7 µmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 10.1 g/dL; Glucose 5.67 mmol/L; C-Reactive Protein 0 mg/dL.
- Day 86 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.079 g/L; Immunoglobulin M 0.117 g/L; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.52 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 7.26 mmol/L.
- Day 170: M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 7.09 g/L; Immunoglobulin A 0.124 g/L; Immunoglobulin M 0.211 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.96 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 68.1 µmol/L; Calcium 2.08 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 6.27 mmol/L.
- Day 282 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.12 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.171 g/L; Immunoglobulin M 0.285 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.99 ×10⁹/L; Absolute Neutrophil 3.28 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 62.8 µmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 6.88 mmol/L.
- Day 366 (ECOG 1): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Immunoglobulin G 6.63 g/L; Immunoglobulin A 0.298 g/L; Immunoglobulin M 0.305 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.49 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 67.2 µmol/L; Calcium 2.2 mmol/L; Albumin 41.1 g/L; Total Protein 5.9 g/dL; Glucose 6.49 mmol/L.
- Day 470: M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.46 mg/dL; Immunoglobulin G 8.19 g/L; Immunoglobulin A 0.267 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.11 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.28 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 67.2 µmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.23 mmol/L.
- Day 554: M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 0.285 g/L; Immunoglobulin M 0.5 g/L; Beta 2 Microglobulin 2.11 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.13 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 638 (ECOG 1): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 3.45 g/L; Immunoglobulin A 0.254 g/L; Immunoglobulin M 0.467 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.06 ×10⁹/L; Absolute Neutrophil 1.55 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.18 mmol/L; Albumin 37.3 g/L; Total Protein 5.4 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day 1: Weight: 100 kg; Height: 152 cm.

Biospecimens (2 samples)
- Sample MMRF_2601_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2601_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
